Surgical pathology report (de-identified scan), TCGA case TCGA-09-1669, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-1669-01A (Primary Tumor).

[page 1 of 7]
[REDACTED]

[REDACTED]

[REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

A. Ovary and fallopian tube, right, salpingo-oophorectomy:

1. Ovary with serous carcinoma, poorly differentiated, FIGO grade III, 13.0 cm;

see comment.

2. Fallopian tube with metastatic serous carcinoma involving the mucosa and wall.

B. Uterus, left fallopian tube and ovary, total abdominal hysterectomy and left

salpingo-oophorectomy:

-Cervix: No significant pathologic abnormality.

-Endometrium: Weakly proliferate pattern.

-Myometrium: Leiomyoma and adenomyosis.

-Serosa: No significant pathologic abnormality.

-Left fallopian tube: No significant pathologic abnormality.

-Left ovary: Two microscopic foci of serous carcinoma, 0.2 cm and 0.35 cm.

-Right and left parametrial tissue: No significant pathologic abnormality.

C. Lymph nodes, right pelvis, lymph node dissection:

1. No tumor identified in eighteen lymph nodes (0/18).

2. Focal benign endosalpingiosis in one lymph node.

D. Lymph nodes, right common iliac, lymph node dissection: No tumor identified in ten lymph nodes (0/10).

E. Lymph nodes, right periaortic, lymph node dissection: No tumor identified in three

[REDACTED]

lymph nodes (0/3).

F. Lymph nodes, left pelvis, lymph node dissection: No tumor identified in eighteen

lymph nodes (0/18).

G. Lymph nodes, left common iliac, lymph node dissection: No tumor identified in two

lymph nodes (0/2).

H. Lymph nodes, left periaortic, lymph node dissection: No tumor identified in eight

lymph nodes (0/8).

I. Omentum, #1, omentectomy: Microscopic focus of metastatic serous carcinoma,

[page 2 of 7]
[REDACTED]
0.3 cm.

J. Omentum, #2, omentectomy: Vascular fibroadipose tissue with focal inflammation.

No tumor identified.

K. Soft tissue, "Left gutter", biopsy: Fibroadipose tissue with mild chronic and acute inflammation. No tumor identified.

L. Soft tissue, "Right gutter", biopsy: Fibroadipose tissue with mild acute inflammation. No tumor identified.

COMMENT:

Ovarian Tumor Synoptic Comment

1. Type of tumor: Serous carcinoma.
2. Grade of tumor: III.
3. Location of tumor: Bilateral (Right - 13.0 cm; Left - Two microscopic foci - 0.2 cm and 0.35 cm (slides B18 and B19).
4. Diameter of tumor: 13.0 cm.
5. Appearance of surface of ovary: Smooth.
6. Condition of capsule: Intact.
7. Appearance of cut surface: Multilocular cysts with papillary excrescences.
8. Color of solid areas: Tan.
9. Necrosis: Focal.
10. Lymphatic/vascular invasion: Not identified.
11. Sites of metastases in pelvis: Right fallopian tube - 1.0 cm (slide A9).
12. Pelvic lymph nodes: 0/48 contain metastatic tumor .
13. Sites of metastases in abdomen: Omentum, 0.3 cm (slide I4).
14. Para-aortic lymph nodes: 0 of 11 contain metastatic tumor.
15. Peritoneal cytology: Positive. Cytology accession number: [REDACTED]
16. Other significant findings: Endosalpingiosis in one lymph node (slide C4).
17. FIGO stage: IIIA.
18. TNM stage: pT3aNxM0.

[REDACTED] reviewed slides A1, A2, and I4 and concurs with the diagnosis. Immunohistochemical studies for ER, PR and Her-2/neu on the tumor will be performed and reported in an addendum.

Specimen(s) Received

Page 2 of 5

A:Right adnexa (FS)
B:Uterus, cervix and left adnexa (FS)
C:Right pelvic lymph nodes
D:Right common iliac lymph nodes
E:Right periaortic lymph nodes
F:Left pelvic lymph nodes
G:Left common iliac lymph nodes
H:Left periaortic lymph nodes
I:Omentum #1
J:Omentum #2
K:Left gutter biopsy
L:Right gutter biopsy

[page 3 of 7]
[REDACTED]

Intraoperative Diagnosis

FS1 (A) Right adnexa, salpingo-oophorectomy: Serous tumor, of at least borderline.

[REDACTED]

B. Uterus, cervix, and left adnexa, total abdominal hysterectomy and bilateral salpingo-oophorectomy:
No gross tumor identified. ([REDACTED])

Clinical History

The patient is a [REDACTED], with a 13-cm complex pelvic mass and history of left breast carcinoma, status post lumpectomy, lymph node dissection, and chemo-radiation. She undergoes total abdominal hysterectomy and bilateral salpingo-oophorectomy.

Gross Description

The specimen is received in twelve parts, each labeled with the patient's name and medical record number.

Parts C-L are received in formalin.

Part A, received fresh and additionally labeled "right adnexa," consists of an ovary with attached fallopian tube that weigh 383.5 gm and measure 15.0 x 14.0 x 10.0 cm. The ovary capsule is intact with

multiloculated cysts, and the external surface is smooth with no tumor or masses seen on the surface.

Upon sectioning of the ovary, there are multiple papillary excrescences. There are no hemorrhagic or

obvious necrotic areas. The cystic fluid is brown. The ovarian mass itself is ~13.0 cm. There is no

obvious grossly normal ovarian tissue present. The fallopian tube measures ~7.0 cm in length. It is

difficult to assess the diameter given that there appears to be tumor involvement of the fallopian tube. In

the most normal area of the fallopian tube, the diameter is ~0.7 cm. A frozen section is taken of the

ovarian mass, with the remnant submitted in cassette A1.

Cassettes A2-A7: Representative sections of tumor.

Cassette A8: Possible fallopian tube with involvement of tumor.

Cassettes A9-A10: Fallopian tube with possible involvement of tumor.

Part B, received fresh and additionally labeled "2 - uterus, cervix + left adnexa," consists of uterus, cervix,

and attached left ovary with tube, that weigh in total 125.5 gm. The uterus and cervix together measure

8.0 cm from superior to inferior, 5.5 cm from medial to lateral, 3.0 cm from anterior to posterior. The left

ovary measures 2.6 x 1.5 x 0.7 cm, while the fallopian tube measures 5.5 cm in length and 0.7 cm in

diameter. The cervix itself measures 3.2 cm. The uterus is opened along its lateral border. There is no

gross tumor identified. The endometrium is 0.3 cm thick and the myometrium is 4.0 cm thick. Within the

myometrium of the anterior cervix, there are two leiomyomas. The ovary and

fallopian tube are grossly

[page 4 of 7]
[REDACTED]

normal without any apparent lesions. The right parametrial tissue measures 4.4 x 1.2 x 1.4 cm, and the left parametrial tissue measures 2.0 x 0.8 x 0.6 cm. There are no gross lesions or masses within this tissue. The anterior uterus is inked in blue, while the posterior is inked in black. Representative sections are submitted as follows:
Cassette B1: Anterior cervix.
Cassette B2: Posterior cervix.
Cassette B3: Leiomyoma in the anterior uterus.
Page 3 of 5

Cassette B4: Leiomyoma in the anterior uterus.
Cassette B5: Possible leiomyoma within the myometrium of the anterior uterus near the corpus.
Cassettes B6-B7: Posterior endomyometrium.
Cassette B8: Left parametrium, entirely submitted.
Cassettes B9-B11: Right parametrium, entirely submitted.
Cassettes B12-B13: Fallopian tube, entirely submitted.
Cassettes B14-B20: Left ovary, entirely submitted along with soft tissue attachment. Part C, additionally labeled "3 - right pelvic lymph nodes," consists of multiple soft, yellow-brown, irregular, glistening, unoriented, fibrofatty tissue fragments measuring 6.0 x 3.5 x 1.0 cm in aggregate. With blunt dissection, multiple firm areas are recognized, ranging from 0.3 to 2.7 cm in greatest diameter. Candidate lymph nodes are submitted as follows:
Cassettes C1-C3: Smallest firm areas, submitted intact.
Cassettes C4-C6: Larger firm areas, bisected.
The remaining soft tissue is returned to the container.
Part D, additionally labeled "4 - right common iliac lymph node," consists of three soft, yellow-brown, irregular, glistening, unoriented, fibrofatty tissue fragments measuring 3.0 x 2.5 x 1.0 cm in aggregate. With blunt dissection, multiple firm areas are recognized, ranging from 1.0 to 1.7 cm in greatest diameter. The specimen is entirely submitted in cassettes D1-D2.
Part E, additionally labeled "5 - right peri-aortic lymph nodes," consists of one soft, yellow-brown, irregular, glistening, unoriented, fibrofatty tissue fragment measuring 3.7 x 2.2 x 0.7 cm. With blunt dissection, multiple firm areas are recognized, ranging from 0.5 to 1.7 cm in greatest dimension. The specimen is entirely submitted in cassettes E1-E3, with the largest firm area bisected and submitted in E3.
Part F, additionally labeled "6 - left pelvic lymph nodes," consists of multiple soft, yellow-brown, irregular, glistening, unoriented, fibrofatty tissue fragments measuring 7.0 x 5.0 x 1.0 cm in aggregate. With blunt dissection, multiple firm areas are recognized, ranging from 0.5 to 2.7 cm in greatest diameter. Candidate lymph nodes are submitted as follows:
Cassettes F1-F2: Firm areas, submitted intact.

[page 5 of 7]
[REDACTED]

Cassette F3: Two firm areas, bisected.

Cassettes F4-F5: Bisected firm areas.

Part G, additionally labeled "7 - left common iliac lymph nodes," consists of multiple soft, yellow-brown, irregular, glistening, unoriented, fibrofatty tissue fragments measuring 3.0 x 2.5 x 0.5 cm in aggregate.

With blunt dissection, multiple firm areas are recognized, ranging from 0.8 to 1.1 cm in greatest diameter.

The specimen is entirely submitted in cassettes G1-G2.

Part H, additionally labeled "8 - left peri-aortic lymph nodes," consists of one soft, yellow-brown, irregular, glistening, unoriented, fibrofatty tissue fragment measuring 2.5 x 2.0 x 1.0 cm. With blunt dissection, two

firm areas are recognized measuring 0.7 and 1.5 cm in greatest diameter. The largest area is bisected, and

the specimen is entirely submitted in cassettes H1-H2, with firm areas in H1 and remaining tissue in H2.

Part I, additionally labeled "9 - omentum 1," consists of one soft, yellow-brown, irregular, glistening, unoriented, fibrofatty tissue fragment measuring 18.0 x 4.5 x 1.0 cm. The specimen is serially sectioned, with representative sections are submitted in cassettes I1-I6, with one section submitted per centimeter.

Part J, additionally labeled "omentum #2," consists of one soft, yellow-brown, irregular, glistening, unoriented, fibrofatty tissue fragment measuring 19.5 x 7.0 x 1.5 cm. The specimen is serially sectioned, and representative sections are submitted in cassettes J1-J5, with one section submitted per centimeter.

Part K, additionally labeled "11 - left gutter biopsy," consists of one soft, yellow-brown, irregular, glistening, unoriented, fibrofatty tissue fragment measuring 1.3 x 0.7 x 0.3 cm. The specimen is entirely submitted in cassette K1.

Part L, additionally labeled "12 - right gutter biopsy," consists of one soft, yellow-brown, irregular,

Page 4 of 5

glistening, unoriented, fibrofatty tissue fragment measuring 0.8 x 0.5 x 0.2 cm. The specimen is entirely submitted in cassette L1.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending

pathologist following review of all pathology slides.

[REDACTED]

Addendum Diagnosis

Addendum Comment

An immunohistochemical test for estrogen and progesterone receptors, as well as for

[page 6 of 7]
[REDACTED]
performed on block A2.

The test for estrogen receptors is positive. There is variable (from weak to strong) nuclear staining in ~40% of tumor cells.

The test for progesterone receptors is positive. There is moderate to strong nuclear staining in ~20% of tumor cells.

Result of Her-2/neu test: This carcinoma is negative for Her-2/neu oncoprotein over-expression.

An immunohistochemical assay was performed using the CB11 monoclonal antibody to Her-2/neu

oncoprotein. The staining intensity of this carcinoma was 1 on a scale of 0-3. The tumor cells show

predominantly cytoplasmic staining, which is nonspecific.

Carcinomas with staining intensity scores of 0 or 1 are considered *negative* for over-expression of Her-2/neu oncoprotein.

Those with a staining intensity score of 2 are considered *borderline*. We and others have observed that many carcinomas with staining intensity scores of 2 do not show gene amplification. All carcinomas with staining intensity scores of 2 are therefore submitted for

FISH testing. The results of the FISH test are issued directly from the molecular cytogenetics laboratory. Carcinomas with staining intensity scores of 3 are considered *positive* for over-expression of Her-2/neu

oncoprotein. Tumors in this category show an excellent correlation between the results of immunohistochemical and FISH testing, and almost always show gene amplification.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics

[REDACTED] They have not been cleared or approved by the U. S. Food and Drug Administration. The

FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of

[REDACTED] as qualified to perform high-complexity clinical testing.

Page 5 of 5

SURGICAL PATHOLOGY REPORT

****ADDENDUM.****

Addendum Comment

An immunohistochemical test for estrogen and progesterone receptors, as well as for Her-2/neu, was performed on block A2.

The test for estrogen receptors is positive. There is variable (from weak to strong) nuclear staining in ~40% of tumor cells.

The test for progesterone receptors is positive. There is moderate to strong nuclear staining in ~20% of tumor cells.

Result of Her-2/neu test: This carcinoma is negative for Her-2/neu oncoprotein over-expression.

An immunohistochemical assay was performed using the CB11 monoclonal antibody

[page 7 of 7]
[REDACTED]

to Her-2/*neu*

oncoprotein. The staining intensity of this carcinoma was 1 on a scale of 0-3. The tumor cells show

predominantly cytoplasmic staining, which is nonspecific.

Carcinomas with staining intensity scores of 0 or 1 are considered *negative* for over-expression of Her-2/*neu* oncoprotein.

Those with a staining intensity score of 2 are considered *borderline*. We and others have observed that many carcinomas with staining

intensity scores of 2 do not show gene amplification. All carcinomas with staining intensity scores of 2 are therefore submitted for

FISH testing. The results of the FISH test are issued directly from the molecular cytogenetics laboratory.

Carcinomas with staining intensity scores of 3 are considered *positive* for over-expression of Her-2/*neu* oncoprotein. Tumors in this

category show an excellent correlation between the results of immunohistochemical and FISH testing, and almost always show gene amplification.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics

[REDACTED] They have not been cleared or approved by the U. S. Food and Drug Administration. The

FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be

regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of

[REDACTED]

Source: NCI Genomic Data Commons file 95f82c8c-ab19-4279-899e-9b47206fbc6b (TCGA-09-1669.7870B5A7-A96C-4E55-B56F-8ECA45918251.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).